CCDI case PBBMLH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3ca5763a-ad13-446a-8f29-a5b47c4bdb5c

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.1 years (1,139 days).

Biospecimens (3 samples)
- Sample 0DCFVM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCFVR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCFVX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
